Somatic mutation profile of tumor specimen 0DT20X from CCDI case PBCJCU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.9 years (2,883 days).
Specimen 0DT20X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 005f02a7-5f27-4ed1-b7a2-834360d2cfe1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DT20M (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b680dd2e-e599-48dc-b61c-9c7f27f06a3b

The open-access MAF lists 38 somatic variants for this specimen: 22 protein-altering or splice-affecting, 8 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 8, Intron 4, 5'Flank 2, Nonsense Mutation 2, 5'UTR 1, Frame Shift Del 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STAG2 | c.3097C>T p.R1033* | Nonsense Mutation (SNP) | VAF 259/281 reads (92%) | catalogued as rs1569520709, COSV54350149; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANGPTL1 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 36/678 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs570797031, COSV99327926; called by muse, mutect2
- ANK2 | c.5338G>C p.E1780Q | Missense Mutation (SNP) | VAF 68/1052 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52190534; called by muse, mutect2
- APOB | c.7837C>A p.Q2613K | Missense Mutation (SNP) | VAF 145/694 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.386); catalogued as COSV51951071; called by muse, mutect2, varscan2
- C10orf90 | c.689_690del p.K230Rfs*46 | Frame Shift Del (DEL) | VAF 97/556 reads (17%) | catalogued as rs759354683; called by mutect2, pindel, varscan2
- EHMT2 | c.1552C>A p.R518S | Missense Mutation (SNP) | VAF 262/619 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV64995831; called by muse, mutect2, varscan2
- KIF14 | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 31/732 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1435446065, COSV100950704; called by muse, mutect2
- MGA | c.7303C>T p.R2435W (on ENST00000219905 / NM_001164273.1; = p.R2226W on NM_001080541.2) | Missense Mutation (SNP) | VAF 393/433 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779811318, COSV54947919; called by muse, mutect2, varscan2
- MYC | c.176C>T p.P59L (on ENST00000377970; = p.P74L on NM_002467.6) | Missense Mutation (SNP) | VAF 146/549 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1294281543, COSV52368162, COSV52368882, COSV52375206; called by muse, mutect2, varscan2
- PTPRQ | c.2194G>A p.E732K (on ENST00000616559; = p.E690K on NM_001145026.2) | Missense Mutation (SNP) | VAF 32/728 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs866364601, COSV99884554; called by muse, mutect2
- TMPRSS7 | c.344G>A p.R115H (on ENST00000452346; = p.R3H on NM_001042575.2) | Missense Mutation (SNP) | VAF 144/324 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.919); catalogued as rs11914332; called by muse, mutect2, varscan2
- WDR11 | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 143/441 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs202173443, COSV54792371; called by muse, mutect2, varscan2
- ZNF316 | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 141/473 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.036); catalogued as rs773200253; called by muse, mutect2, varscan2
- ZNF544 | c.292C>T p.R98* | Nonsense Mutation (SNP) | VAF 125/567 reads (22%) | catalogued as rs758463217, COSV54135148; called by muse, mutect2, varscan2
- CTDNEP1 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 30/244 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- HOXB1 | c.217G>T p.G73W | Missense Mutation (SNP) | VAF 258/797 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NUTM1 | c.442G>C p.V148L | Missense Mutation (SNP) | VAF 132/539 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- OR8D1 | c.73C>A p.L25M | Missense Mutation (SNP) | VAF 34/606 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.863); called by muse, mutect2
- SCARB2 | c.1297T>G p.L433V | Missense Mutation (SNP) | VAF 44/798 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.021); called by muse, mutect2
- SPATA20 | c.1714G>A p.G572S (on ENST00000356488 / NM_001258372.1; = p.G588S on NM_022827.4) | Missense Mutation (SNP) | VAF 37/1102 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- TBL1XR1 | c.938A>T p.D313V | Missense Mutation (SNP) | VAF 225/473 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- WDR87 | c.7868dup p.S2624Vfs*14 | Frame Shift Ins (INS) | VAF 160/675 reads (24%) | called by mutect2, pindel, varscan2
- CDC42BPB | c.4254C>T p.F1418= | Silent (SNP) | VAF 125/453 reads (28%) | called by muse, mutect2, varscan2
- FAM122A | c.33G>A p.E11= | Silent (SNP) | VAF 163/379 reads (43%) | called by muse, mutect2, varscan2
- FAT4 | c.14700C>T p.A4900= | Silent (SNP) | VAF 196/571 reads (34%) | catalogued as rs149897030; called by muse, mutect2, varscan2
- GTF3C1 | c.2325G>A p.P775= | Silent (SNP) | VAF 52/509 reads (10%) | catalogued as rs748271854, COSV100648993; called by muse, mutect2, varscan2
- LNPEP | c.1179C>A p.A393= | Silent (SNP) | VAF 182/419 reads (43%) | called by mutect2, varscan2
- MMP24 | c.1023A>T p.T341= | Silent (SNP) | VAF 300/687 reads (44%) | called by muse, mutect2, varscan2
- OTOP1 | c.270C>T p.S90= | Silent (SNP) | VAF 86/738 reads (12%) | catalogued as rs371259440, COSV56391838; called by muse, mutect2
- ZXDC | c.1929G>A p.S643= | Silent (SNP) | VAF 333/690 reads (48%) | catalogued as rs780296843; called by muse, mutect2, varscan2
- ACSS1 | chr20:25058150 C>T | 5'Flank (SNP) | VAF 144/260 reads (55%) | catalogued as rs1488380962; called by muse, mutect2, varscan2
- ASIC3 | c.-45C>A | 5'UTR (SNP) | VAF 12/109 reads (11%) | called by muse, mutect2, varscan2
- BCL2L2 | chr14:23302405 G>T | 5'Flank (SNP) | VAF 105/330 reads (32%) | called by muse, mutect2, varscan2
- HTN3 | c.51+17G>T | Intron (SNP) | VAF 146/498 reads (29%) | called by mutect2, varscan2
- LILRB3 | c.*2C>T | 3'UTR (SNP) | VAF 311/692 reads (45%) | called by muse, mutect2, varscan2
- RCE1 | c.372+58G>A | Intron (SNP) | VAF 18/264 reads (7%) | called by muse, mutect2
- TSPAN32 | c.628-16G>T | Intron (SNP) | VAF 10/186 reads (5%) | called by muse, mutect2
- WDR75 | c.216+311C>T | Intron (SNP) | VAF 235/411 reads (57%) | catalogued as rs542985249; called by muse, mutect2, varscan2
